Somatic mutation profile of tumor specimen 0DDPQ4 from CCDI case PBBNST, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.3 years (5,965 days).
Specimen 0DDPQ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 046f0bb3-7d74-4955-a6cc-c9cb99d0c48b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDPQ5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60c3de04-a885-4f27-b489-337c19c4fd11

The open-access MAF lists 40 somatic variants for this specimen: 23 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 12, Intron 4, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 96/475 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ADAMTS5 | c.1886G>T p.R629L | Missense Mutation (SNP) | VAF 86/584 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53177017; called by muse, mutect2, varscan2
- CDKL5 | c.1553C>A p.P518Q | Missense Mutation (SNP) | VAF 72/979 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66110123; called by muse, mutect2
- CLDN23 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 104/378 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs750510804, COSV67731679; called by muse, mutect2, varscan2
- FLNA | c.4579G>A p.D1527N | Missense Mutation (SNP) | VAF 74/907 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs782537273; called by muse, mutect2
- MET | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 72/923 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59262341; called by muse, mutect2
- MYH2 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 285/1341 reads (21%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.952); catalogued as COSV55437959; called by muse, mutect2, varscan2
- PCDHGA2 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 99/401 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs779983817; called by muse, mutect2, varscan2
- SLC5A11 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 37/1087 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368327872; called by muse, mutect2
- UBE2Q1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 114/599 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV52724737; called by muse, mutect2, varscan2
- UBXN8 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 108/534 reads (20%) | catalogued as rs754585716, COSV55664190; called by muse, mutect2, varscan2
- ACACB | c.4807G>T p.D1603Y | Missense Mutation (SNP) | VAF 171/792 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS20 | c.2355dup p.E786Rfs*12 | Frame Shift Ins (INS) | VAF 208/1013 reads (21%) | called by mutect2, varscan2
- ADPRHL1 | c.5248G>A p.E1750K | Missense Mutation (SNP) | VAF 58/845 reads (7%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2
- BANK1 | c.568G>C p.A190P | Missense Mutation (SNP) | VAF 88/1002 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- CAPN15 | c.1514G>A p.G505D | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- G6PC2 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 174/863 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO1E | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 168/805 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TBXA2R | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 190/908 reads (21%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.879); called by muse, mutect2
- TDRD6 | c.3448G>A p.A1150T | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- TEX11 | c.2342C>T p.A781V (on ENST00000344304; = p.A766V on NM_031276.3) | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ZBTB46 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 26/782 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ZNF226 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 134/617 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AATK | c.3351C>T p.F1117= (on ENST00000326724 / NM_001080395.3; = p.F1014= on NM_004920.2) | Silent (SNP) | VAF 74/1090 reads (7%) | catalogued as rs773298565; called by muse, mutect2
- CACNG3 | c.177C>T p.T59= | Silent (SNP) | VAF 61/481 reads (13%) | called by muse, mutect2, varscan2
- DUOX1 | c.2208C>T p.S736= | Silent (SNP) | VAF 94/605 reads (16%) | catalogued as rs372398306, COSV58477009; called by muse, mutect2, varscan2
- EBF4 | c.1068C>T p.V356= (on ENST00000609451; = p.V352= on NM_001110514.1) | Silent (SNP) | VAF 123/781 reads (16%) | catalogued as rs1232370015; called by muse, mutect2, varscan2
- JAG2 | c.1539C>T p.C513= | Silent (SNP) | VAF 42/418 reads (10%) | catalogued as rs768075965; called by muse, mutect2, varscan2
- KPRP | c.366C>T p.C122= | Silent (SNP) | VAF 139/765 reads (18%) | catalogued as rs757154193, COSV64222064; called by muse, mutect2, varscan2
- LTBP4 | c.4791T>C p.D1597= (on ENST00000308370 / NM_001042544.1; = p.D1560= on NM_003573.2) | Silent (SNP) | VAF 129/662 reads (19%) | called by muse, mutect2, varscan2
- MECP2 | c.1317G>A p.A439= | Silent (SNP) | VAF 40/903 reads (4%) | catalogued as rs146632223, COSV100318544, COSV57656556; ClinVar: benign / likely benign; called by muse, mutect2
- PPBP | c.276C>T p.V92= | Silent (SNP) | VAF 111/600 reads (19%) | catalogued as rs773999304, COSV99933011, COSV99933022; called by muse, mutect2, varscan2
- PRRC2C | c.2235C>T p.Y745= (on ENST00000367742; = p.Y743= on NM_015172.4) | Silent (SNP) | VAF 74/1148 reads (6%) | called by muse, mutect2
- SLITRK2 | c.897G>A p.P299= | Silent (SNP) | VAF 86/1238 reads (7%) | catalogued as rs782289726; called by muse, mutect2
- SYNE1 | c.19072C>T p.L6358= (on ENST00000367255 / NM_182961.4; = p.L6287= on NM_033071.3) | Silent (SNP) | VAF 63/1486 reads (4%) | called by muse, mutect2
- EIF4H | c.607+38G>A | Intron (SNP) | VAF 39/913 reads (4%) | called by muse, mutect2
- GM2A | c.426+94A>G | Intron (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- MZF1 | c.*99G>A | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, varscan2
- PPP6R1 | c.619-15C>T | Intron (SNP) | VAF 119/587 reads (20%) | called by muse, mutect2, varscan2
- TEX261 | c.373-35C>T | Intron (SNP) | VAF 50/199 reads (25%) | catalogued as rs781917191; called by muse, mutect2, varscan2
